Somatic mutation profile of tumor specimen 0DRMOI from CCDI case PBCFJW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.5 years (6,385 days).
Specimen 0DRMOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a697647-7741-4ec5-99bb-084da68a887e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRMOL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af1c81ba-a0b3-4b10-99f5-15acce9ad9e2

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 2, Missense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG3 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747467847; called by muse, varscan2
- EIF3L | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MBD4 | c.1665+8T>G | Splice Region (SNP) | VAF 56/364 reads (15%) | called by muse, mutect2, varscan2
- BRD1 | c.112A>C p.R38= | Silent (SNP) | VAF 53/323 reads (16%) | called by muse, mutect2, varscan2
- POTEB3 | c.861G>T p.V287= | Silent (SNP) | VAF 36/1338 reads (3%) | called by muse, mutect2
- SSTR4 | c.1011A>G p.G337= | Silent (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 6/65 reads (9%) | catalogued as COSV99987084; called by muse, varscan2
- KCTD3 | c.1563-61_1563-55del | Intron (DEL) | VAF 10/84 reads (12%) | called by mutect2, varscan2
